Surgical pathology report (de-identified scan), TCGA case TCGA-37-A5EM, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Cureline, specimen TCGA-37-A5EM-01A (Primary Tumor).

Index	Specimen label	Clinical Site #	Case #	DOB (mm/dd/yyyy)	Sex	Ethnicity (Race)	Clinical Diagnosis	Date of procurement	Anatomical Site	Tumor Location	Tissue Specification	Specimen Matrix	Specimen Format	Container	Number of containers	Amount/p or container	Unit	Type of Procurement	Histological description	Grade	TNM Stage (T)	TNM Stage (N)	TNM Stage (M)	Treatment type	Component of treatment (Chemo / Horm Th Details)	Tumor cell %
					Male	Caucasian (White)	Lung cancer		Left lung	Primary	Tumor	Tissue	OCT	block	1	200	mg	surgery	Squamous cell carcinoma	3	2	0	0	none	n/a	65
					Male	Caucasian (White)	Lung cancer		Blood	n/a	Normal	Blood	frozen	tube	1	4	ml	blood draw	n/a	n/a	n/a	n/a	n/a	none	n/a	n/a

ICD-O-3

Carcinoma, squamous cell NOS
8070/3

Site CCF Lung, upper lobe C34.1
path O Lung, NOS C34.9

Criteria	12/19/12	Yes	No

Source: NCI Genomic Data Commons file 5fde0d69-1c68-48ec-9117-78057a6f8558 (TCGA-37-A5EM.5D9E8908-FE51-46B4-917C-4A0F6FAA3E38.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).